Somatic mutation profile of tumor specimen ALCH-B3DD-TTP1-A (aliquot ALCH-B3DD-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B3DD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.7 years (22,542 days).
Specimen ALCH-B3DD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cc61fa4-4ae9-45f1-b245-2fe943112dff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DD-NB1-A (Blood Derived Normal), aliquot ALCH-B3DD-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c90dae1b-add3-4427-ac21-0c0ef28a385f

The open-access MAF lists 261 somatic variants for this specimen: 180 protein-altering or splice-affecting, 54 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 54, Nonsense Mutation 12, Intron 12, Splice Site 4, 5'Flank 4, 5'UTR 4, RNA 3, 3'UTR 3, Splice Region 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 55/427 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SNRPD3 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 9/102 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV53182727, COSV53183815, COSV99307458; called by muse, mutect2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 19/229 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA13 | c.8083T>A p.Y2695N | Missense Mutation (SNP) | VAF 42/511 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as rs776319362; called by muse, mutect2
- ADAMDEC1 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.464); catalogued as COSV56474062; called by muse, mutect2
- AMPH | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57744364; called by muse, mutect2
- ANKRD26 | c.3845G>T p.R1282I | Missense Mutation (SNP) | VAF 50/760 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1289561945, COSV99058086; called by muse, mutect2
- ATF7IP | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 29/142 reads (20%) | catalogued as COSV53767430; called by muse, mutect2, varscan2
- ATR | c.7591C>G p.L2531V | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.268); catalogued as COSV100637643; called by muse, mutect2
- B3GNT9 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as rs780449270; called by muse, mutect2, varscan2
- CDH8 | c.2233C>G p.Q745E | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as rs1353305621, COSV54860210; called by muse, mutect2
- CHRNA4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1247664860, COSV64719141; called by muse, mutect2
- CSMD1 | c.7438G>T p.G2480C (on ENST00000520002; = p.G2479C on NM_033225.6) | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59298076; called by muse, mutect2
- CTNND1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV62382550; called by muse, mutect2
- DGKB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/287 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV51783361; called by muse, mutect2
- DGLUCY | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs747244719, COSV56365580; called by muse, mutect2
- FCRL5 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100708908, COSV62513638; called by muse, mutect2
- FYCO1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 30/876 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV56121138; called by muse, mutect2
- GCKR | c.1484T>A p.V495E | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53106803; called by muse, mutect2
- GPHN | c.2158G>A p.V720M (on ENST00000315266 / NM_001377519.1; = p.V753M on NM_020806.5) | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as rs1181551943, COSV59485834; called by muse, mutect2
- GRID1 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV60018923; called by muse, mutect2
- GRIN2D | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV54377910; called by muse, mutect2
- IMP4 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52091821, COSV52092211; called by muse, mutect2
- ITGA4 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 12/205 reads (6%) | catalogued as COSV99275806; called by muse, mutect2
- JAKMIP1 | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV51529027; called by muse, mutect2
- KRT31 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs770489812; called by muse, mutect2
- LAMA1 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 18/662 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV67537053; called by muse, mutect2
- LRP1B | c.9266C>A p.P3089H | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67202433; called by muse, mutect2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2
- MACROD2 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54040334; called by muse, mutect2
- MAP1B | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.477); catalogued as COSV57095824; called by muse, mutect2
- MAPK8IP3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.864); catalogued as COSV50189368; called by muse, mutect2
- MCM9 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60324310, COSV60327211; called by muse, mutect2
- MEOX2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 48/634 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs868107417, COSV56287712; called by muse, mutect2
- NTS | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs776162417; called by muse, mutect2
- OPN3 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1477189330; called by muse, mutect2
- OR13G1 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62945278; called by muse, mutect2
- OSER1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750300001, COSV54854040; called by muse, mutect2, varscan2
- OTOGL | c.5872G>T p.G1958C (on ENST00000547103; = p.G1949C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100087557; called by muse, mutect2
- OVCH2 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 10/238 reads (4%) | catalogued as rs1446387367; called by muse, mutect2
- PCDHB10 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.215); catalogued as rs782338014; called by muse, mutect2
- PHKA1 | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 17/500 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV59805423; called by muse, mutect2
- PLEKHA3 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 12/363 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs1289433037; called by muse, mutect2
- PTCH1 | c.3982G>T p.E1328* | Nonsense Mutation (SNP) | VAF 7/152 reads (5%) | catalogued as COSV59466057; called by muse, mutect2
- PXDNL | c.4222C>A p.R1408S | Missense Mutation (SNP) | VAF 36/445 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.078); catalogued as COSV62487421; called by muse, mutect2
- PZP | c.3639G>C p.E1213D | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54365662; called by muse, mutect2, varscan2
- RYR2 | c.5038G>T p.V1680L | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV100771091; called by muse, mutect2
- SLC10A7 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 25/536 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs1246166333; called by muse, mutect2
- SLC25A26 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316867548; called by muse, mutect2
- SPHKAP | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60867905; called by muse, mutect2
- SPTA1 | c.4867C>G p.L1623V | Missense Mutation (SNP) | VAF 36/673 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63756706; called by muse, mutect2
- SRSF4 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 31/413 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs778992152; called by muse, mutect2
- SYNE1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 32/546 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs560155321, COSV54928364; ClinVar: uncertain significance; called by muse, mutect2
- TAS2R38 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV101516592, COSV71885532; called by muse, mutect2, varscan2
- TBC1D30 | c.2397G>T p.Q799H (on ENST00000542120; = p.Q636H on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV57486137; called by muse, mutect2
- WDR33 | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as COSV59249209; called by muse, mutect2
- WDR49 | c.2023C>A p.L675M (on ENST00000308378 / NM_001366158.1; = p.L1016M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1022858219; called by muse, mutect2
- YIPF7 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.634); catalogued as COSV100274704; called by muse, mutect2
- ZNF423 | c.1149C>A p.S383R (on ENST00000563137 / NM_001379286.1; = p.S375R on NM_015069.4) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV52195156; called by muse, mutect2, varscan2
- ZNF729 | c.3746C>A p.A1249D | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV62603379, COSV62604022; called by muse, mutect2
- ACTA1 | c.1052T>A p.L351Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRG7 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- AMIGO1 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ANHX | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ANLN | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 15/222 reads (7%) | called by muse, mutect2
- ANXA1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 38/435 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AOPEP | c.1239A>C p.Q413H | Missense Mutation (SNP) | VAF 78/600 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ARFGEF1 | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 21/570 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- ARGFX | c.165C>A p.N55K | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP12 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ARHGEF6 | c.1558G>T p.G520C | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP11B | c.3453-1G>T p.X1151_splice | Splice Site (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- ATP1A1 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 22/506 reads (4%) | called by muse, mutect2
- C8A | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CASP12 | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- CDH2 | c.2651A>T p.Y884F | Missense Mutation (SNP) | VAF 38/739 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2
- CENPK | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- CHST13 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by mutect2, varscan2
- CLEC1A | c.95A>T p.H32L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- COLGALT2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.215); called by muse, mutect2
- CRPPA | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2A7 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX18 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 13/414 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- DGKB | c.2178G>T p.M726I | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.342); called by muse, mutect2
- DKK2 | c.742T>A p.S248T | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2
- DMD | c.8503G>T p.G2835* | Nonsense Mutation (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- DNAH11 | c.2164C>A p.P722T | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2
- DNAH2 | c.3941G>A p.R1314K | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH3 | c.12110C>T p.S4037F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAJC2 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- DNM2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 27/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DST | c.4893G>T p.K1631N | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DTHD1 | c.953G>T p.S318I (on ENST00000456874; = p.S153I on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- EPRS1 | c.3298G>T p.E1100* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- FAM200B | c.872G>C p.C291S | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM83B | c.1964A>C p.Q655P | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT2 | c.12043C>A p.P4015T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2
- FGD4 | c.1363G>T p.V455L | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- FLNC | c.5077G>A p.D1693N | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.25); called by muse, mutect2
- GABRA6 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 22/650 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GHRHR | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- GPR174 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.065); called by muse, mutect2
- HTR3B | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- IARS2 | c.467A>T p.H156L | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IQGAP2 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGAM | c.2479C>A p.L827M (on ENST00000648685 / NM_001145808.2; = p.L826M on NM_000632.4) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- KDF1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF4B | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 42/623 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2
- KRT79 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- LRRC74B | c.234A>T p.Q78H | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.954); called by muse, mutect2
- MAGEB3 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- MCM6 | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.284); called by muse, mutect2
- MGAT5 | c.1844G>T p.R615I | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- MUC1 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC16 | c.36326T>C p.L12109P | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- MXRA5 | c.5581C>A p.Q1861K | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.297); called by muse, mutect2
- NAV3 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 17/374 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- NETO1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 23/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NPTX2 | c.810dup p.A271Cfs*36 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- NTNG1 | c.1197C>A p.C399* | Nonsense Mutation (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- NUDT1 | c.293T>A p.V98E (on ENST00000397048 / NM_198952.1; = p.V75E on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.102); called by muse, mutect2
- NUMA1 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2
- OAS3 | c.460+3G>A | Splice Region (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- OR2A12 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- OR2G3 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR2T5 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 32/856 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- OR5P2 | c.822C>A p.Y274* | Nonsense Mutation (SNP) | VAF 14/418 reads (3%) | called by muse, mutect2
- OVCH1 | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- P2RY6 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- P3H2 | c.1220A>T p.D407V | Missense Mutation (SNP) | VAF 61/651 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.231); called by muse, mutect2
- PBX2 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PCDH7 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.734); called by muse, mutect2
- PCDHA1 | c.2323G>T p.G775C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- PCDHA1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2
- PDCD11 | c.4780G>T p.A1594S | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- PIEZO2 | c.6148G>T p.A2050S | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- PIK3R4 | c.358T>A p.L120M | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB1 | c.246+1G>T p.X82_splice | Splice Site (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- PLXNA3 | c.2203G>C p.V735L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- POSTN | c.398C>G p.T133S | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPARGC1B | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); called by muse, mutect2
- PPOX | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PRKAG3 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2
- RARB | c.314G>T p.C105F (on ENST00000383772 / NM_001290216.2; = p.C98F on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2
- RBM12 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RIMS2 | c.4206-2A>G p.X1402_splice (on ENST00000666250 / NM_001348490.2; = p.X973_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 19/225 reads (8%) | called by muse, mutect2
- RRP12 | c.3038G>T p.R1013L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- RTL10 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- SAV1 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- SEMA3A | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 34/453 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA5A | c.2385G>T p.Q795H | Missense Mutation (SNP) | VAF 25/446 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); called by muse, mutect2
- SENP7 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- SI | c.2644G>C p.G882R | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIPA1L2 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC30A10 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2
- SLC9B2 | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 24/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SLCO1C1 | c.1939G>T p.V647L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- SMARCC1 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 18/456 reads (4%) | called by muse, mutect2
- SNX31 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SOHLH2 | c.92A>C p.Y31S | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2
- SORCS3 | c.2746C>A p.H916N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ST3GAL5 | c.433G>A p.E145K (on ENST00000377332; = p.E185K on NM_003896.4) | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- SUPT20HL2 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 8/74 reads (11%) | called by pindel, varscan2*
- TAF1L | c.2165A>C p.Y722S | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TBC1D3P2 | n.471G>C | Splice Region (SNP) | VAF 30/420 reads (7%) | called by muse, mutect2
- TEX13A | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.331); called by muse, mutect2
- TEX15 | c.6040C>A p.H2014N (on ENST00000256246; = p.H2397N on NM_001350162.2) | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- TLR4 | c.200G>T p.R67M (on ENST00000355622 / NM_138554.5; = p.R27M on NM_003266.4) | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TMEM132C | c.2265G>T p.W755C | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNN | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); called by muse, mutect2
- TRAF6 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 15/488 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- TRIM29 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- TRRAP | c.2145G>T p.K715N | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UTRN | c.5876G>A p.R1959K | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.29); called by muse, varscan2
- VCAM1 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2
- XIRP2 | c.134A>T p.K45M (on ENST00000628543; = p.K220M on NM_152381.6) | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ZFP62 | c.727C>T p.H243Y (on ENST00000502412 / NM_001377944.1; = p.H210Y on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- ZNF239 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.089); called by muse, mutect2
- ZP4 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS2 | c.3607C>A p.R1203= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- ADGRF4 | c.42G>C p.G14= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as rs1167751420; called by muse, mutect2, varscan2
- AKAP11 | c.3363T>C p.T1121= | Silent (SNP) | VAF 8/256 reads (3%) | called by muse, mutect2
- ALPI | c.453G>A p.V151= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- ANXA1 | c.138G>T p.S46= | Silent (SNP) | VAF 39/442 reads (9%) | catalogued as COSV99973931; called by muse, mutect2
- ARHGAP4 | c.1224C>T p.S408= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- BGN | c.732C>T p.I244= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as rs782111656, COSV100525114; called by muse, mutect2
- CHD9 | c.1437A>G p.L479= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1182379484; called by muse, mutect2
- CNGA4 | c.1662T>A p.P554= | Silent (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2
- COL12A1 | c.2895G>T p.L965= | Silent (SNP) | VAF 30/455 reads (7%) | called by muse, mutect2
- CPZ | c.1461C>T p.L487= (on ENST00000360986 / NM_001014447.3; = p.L476= on NM_003652.3) | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV59925394; called by muse, mutect2
- CWH43 | c.1197G>T p.L399= | Silent (SNP) | VAF 16/317 reads (5%) | called by muse, mutect2
- DOCK2 | c.642G>C p.R214= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- ECM1 | c.1263C>T p.L421= | Silent (SNP) | VAF 21/464 reads (5%) | called by muse, mutect2
- ERBB4 | c.1311C>G p.L437= | Silent (SNP) | VAF 40/539 reads (7%) | called by muse, mutect2
- FSHR | c.732G>T p.L244= | Silent (SNP) | VAF 34/646 reads (5%) | catalogued as COSV58628964; called by muse, mutect2
- GALC | c.300G>T p.V100= | Silent (SNP) | VAF 42/850 reads (5%) | called by muse, mutect2
- GBP6 | c.549C>T p.F183= | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- HECA | c.96G>A p.A32= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- IGF2BP3 | c.933G>T p.T311= | Silent (SNP) | VAF 20/238 reads (8%) | catalogued as rs144657909; called by muse, mutect2
- INSC | c.1266C>A p.A422= | Silent (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- KCNRG | c.642G>A p.L214= | Silent (SNP) | VAF 17/354 reads (5%) | called by muse, mutect2
- MCEMP1 | c.444C>A p.T148= | Silent (SNP) | VAF 22/263 reads (8%) | called by muse, mutect2
- MED12L | c.2439C>A p.I813= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- MTR | c.1143A>T p.A381= | Silent (SNP) | VAF 19/570 reads (3%) | called by muse, mutect2
- OR2A12 | c.180C>A p.V60= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV68821719; called by muse, mutect2, varscan2
- OR2F2 | c.192C>G p.T64= | Silent (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- OR4S2 | c.708C>T p.S236= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV56746901; called by muse, mutect2
- OSBPL1A | c.252G>T p.P84= | Silent (SNP) | VAF 14/295 reads (5%) | called by muse, mutect2
- PCDHB8 | c.540G>T p.R180= | Silent (SNP) | VAF 14/318 reads (4%) | called by muse, mutect2
- PKD1L1 | c.7842C>A p.L2614= | Silent (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- POLRMT | c.3540G>T p.L1180= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- PSG2 | c.321G>C p.L107= | Silent (SNP) | VAF 20/398 reads (5%) | catalogued as rs747167637, COSV68884890; called by muse, mutect2
- PTDSS1 | c.1047C>T p.R349= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs145261755, COSV61266290; ClinVar: likely benign; called by muse, mutect2
- SCN3A | c.402C>T p.I134= | Silent (SNP) | VAF 44/549 reads (8%) | called by muse, mutect2
- SEMA3F | c.1524G>T p.L508= | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- SEMA6A | c.864C>T p.D288= | Silent (SNP) | VAF 44/460 reads (10%) | called by muse, mutect2
- SLC22A24 | c.708G>C p.V236= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- SLC36A4 | c.309T>A p.S103= | Silent (SNP) | VAF 13/340 reads (4%) | called by muse, mutect2
- SMARCA2 | c.1851G>T p.L617= | Silent (SNP) | VAF 17/306 reads (6%) | called by muse, mutect2
- SRPRA | c.360C>T p.L120= | Silent (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- SZT2 | c.2052G>A p.L684= | Silent (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- TAF1L | c.226C>T p.L76= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs751504623, COSV54263418; called by muse, mutect2, varscan2
- TCERG1L | c.99G>A p.P33= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- TEP1 | c.1428C>T p.R476= | Silent (SNP) | VAF 14/278 reads (5%) | called by muse, mutect2
- THSD7A | c.1176C>A p.I392= | Silent (SNP) | VAF 48/576 reads (8%) | called by muse, mutect2
- TMEM229B | c.234C>T p.L78= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- TNFSF10 | c.510G>A p.R170= | Silent (SNP) | VAF 14/271 reads (5%) | called by muse, mutect2
- TRAJ32 | c.30C>G p.L10= | Silent (SNP) | VAF 10/339 reads (3%) | called by muse, mutect2
- TRIM2 | c.1107G>C p.L369= (on ENST00000437508; = p.L396= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- TRIM42 | c.1542A>T p.T514= | Silent (SNP) | VAF 13/227 reads (6%) | called by muse, mutect2
- TYR | c.750G>A p.E250= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- ZNF536 | c.3447C>A p.I1149= | Silent (SNP) | VAF 7/166 reads (4%) | catalogued as COSV100835455, COSV62836506; called by muse, mutect2
- ZNF83 | c.1437C>T p.H479= | Silent (SNP) | VAF 12/179 reads (7%) | called by muse, mutect2
- ADGRV1 | c.4378+30G>C | Intron (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- AL353804.7 | chrX:73851524 C>A | 3'Flank (SNP) | VAF 24/686 reads (3%) | called by muse, mutect2
- CAPS2 | c.1670-2734G>T | Intron (SNP) | VAF 9/219 reads (4%) | called by muse, mutect2
- CASP1 | c.-12G>A | 5'UTR (SNP) | VAF 31/615 reads (5%) | called by muse, mutect2
- CCDC39 | c.1527+10C>A | Intron (SNP) | VAF 30/370 reads (8%) | called by muse, mutect2
- CES1 | c.-32T>A | 5'UTR (SNP) | VAF 13/273 reads (5%) | called by muse, mutect2
- DXO | chr6:31972227 C>T | 5'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- FN1 | c.2122+23G>T | Intron (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- GLTPP1 | chr11:18188988 C>A | 5'Flank (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- GUCY2EP | n.1052G>T | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- HSP90AB3P | n.1169C>A | RNA (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- IL16 | c.-220G>T | 5'UTR (SNP) | VAF 8/124 reads (6%) | catalogued as rs1338605839; called by muse, mutect2
- LHX2 | c.-1G>A | 5'UTR (SNP) | VAF 5/69 reads (7%) | catalogued as rs1198542108; called by muse, mutect2
- LPAR5 | c.*162A>G | 3'UTR (SNP) | VAF 12/94 reads (13%) | catalogued as rs1402337406; called by muse, mutect2
- MAPK8 | c.1061-54G>C | Intron (SNP) | VAF 12/326 reads (4%) | called by muse, mutect2
- MFSD14C | n.704+3415G>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- NDE1 | chr16:15664775 C>T | 5'Flank (SNP) | VAF 19/299 reads (6%) | called by muse, mutect2
- NDUFS7 | c.409-11C>T | Intron (SNP) | VAF 17/166 reads (10%) | catalogued as rs773102111; called by muse, mutect2, varscan2
- OR4F13P | n.1219C>T | RNA (SNP) | VAF 26/229 reads (11%) | called by muse, mutect2, varscan2
- PIP5K1A | c.85+11C>T | Intron (SNP) | VAF 10/236 reads (4%) | catalogued as rs1276223714; called by muse, mutect2
- RGS6 | c.1368+11086C>A | Intron (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- RINT1 | c.89-993A>G | Intron (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- RN7SL545P | chr15:22431960 C>G | 5'Flank (SNP) | VAF 20/436 reads (5%) | called by muse, mutect2
- SHH | c.*2773G>T | 3'UTR (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
- SUSD1 | c.2150-177G>T | Intron (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- TRPM2 | c.3462-1248G>T | Intron (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- ZBTB24 | c.*150C>T | 3'UTR (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
